Somatic mutation profile of tumor specimen C3L-08255-01 (aliquot CPT0477430006) from CPTAC case C3L-08255, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 70.4 years (25,714 days).
Specimen C3L-08255-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Antrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b3b0a705-9d29-42cd-88bf-194d61573760.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-08255-31 (Blood Derived Normal), aliquot CPT0475630003; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fd51c6db-1278-45bf-be25-ac0bd50ff557

The open-access MAF lists 45 somatic variants for this specimen: 36 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 7, Frame Shift Del 2, Splice Site 1, Intron 1, Splice Region 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGAP6 | c.1561C>T p.R521C | Missense Mutation (SNP) | VAF 34/286 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.673); catalogued as rs777197971; called by mutect2, varscan2
- BOC | c.355C>G p.P119A | Missense Mutation (SNP) | VAF 54/472 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.158); catalogued as COSV56355445; called by mutect2, varscan2
- DNMT3A | c.2026C>T p.R676W | Missense Mutation (SNP) | VAF 44/304 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as rs375399431, COSV53043522; called by mutect2, varscan2
- ERAL1 | c.383C>T p.T128I | Missense Mutation (SNP) | VAF 34/340 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763723857; called by mutect2, varscan2
- FREM1 | c.173G>T p.C58F | Missense Mutation (SNP) | VAF 33/263 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747607735, COSV66525704; called by mutect2, varscan2
- HYDIN | c.6100C>T p.R2034W | Missense Mutation (SNP) | VAF 28/268 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs201606263, COSV59250010; called by mutect2, varscan2
- KCNG2 | c.437C>T p.P146L | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs1345289752; called by mutect2, varscan2
- KRT79 | c.1121G>A p.G374E | Missense Mutation (SNP) | VAF 28/257 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as COSV57939468; called by mutect2, varscan2
- NECTIN1 | c.1138C>T p.R380W | Missense Mutation (SNP) | VAF 32/305 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as rs376335229; called by mutect2, varscan2
- SHANK1 | c.6274G>A p.A2092T | Missense Mutation (SNP) | VAF 51/492 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as rs201633631; called by mutect2, varscan2
- SP7 | c.952C>A p.H318N | Missense Mutation (SNP) | VAF 38/334 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100382042; called by mutect2, varscan2
- SPEG | c.8129C>T p.T2710M | Missense Mutation (SNP) | VAF 42/216 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs865794814, COSV56663107; called by mutect2, varscan2
- SYTL4 | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767254640; called by mutect2, varscan2
- TEKT2 | c.530G>A p.R177Q | Missense Mutation (SNP) | VAF 29/262 reads (11%) | SIFT tolerated (0.64); PolyPhen benign (0.089); catalogued as rs146762659; called by mutect2, varscan2
- TLE6 | c.1313G>T p.G438V (on ENST00000246112 / NM_001143986.2; = p.G315V on NM_024760.3) | Missense Mutation (SNP) | VAF 32/310 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as rs1257108715; called by mutect2, varscan2
- ACACB | c.4264A>G p.I1422V | Missense Mutation (SNP) | VAF 34/322 reads (11%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- AK7 | c.1282del p.E428Kfs*14 | Frame Shift Del (DEL) | VAF 33/286 reads (12%) | called by mutect2, pindel, varscan2
- ANHX | c.837C>A p.V279= | Splice Region (SNP) | VAF 52/249 reads (21%) | called by mutect2, varscan2
- C10orf71 | c.2311G>A p.E771K | Missense Mutation (SNP) | VAF 60/318 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.031); called by mutect2, varscan2
- DNAH7 | c.10211G>A p.R3404K | Missense Mutation (SNP) | VAF 34/275 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by mutect2, varscan2
- GJD3 | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 34/246 reads (14%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.489); called by mutect2, varscan2
- HARS2 | c.476G>T p.R159L | Missense Mutation (SNP) | VAF 22/244 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by mutect2, varscan2
- IQANK1 | c.1286del p.G429Afs*28 | Frame Shift Del (DEL) | VAF 68/325 reads (21%) | called by mutect2, pindel, varscan2
- MPHOSPH9 | c.2231T>C p.M744T | Missense Mutation (SNP) | VAF 25/175 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- MROH9 | c.1718C>T p.S573L | Missense Mutation (SNP) | VAF 19/178 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.053); called by mutect2, varscan2
- NBN | c.1124+1del p.X375_splice | Splice Site (DEL) | VAF 43/284 reads (15%) | called by mutect2, pindel, varscan2
- PGLYRP2 | c.1724T>A p.L575H | Missense Mutation (SNP) | VAF 22/229 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.221); called by mutect2, varscan2
- PRDM15 | c.1963A>T p.I655F | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by mutect2, varscan2
- SHROOM2 | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 64/239 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.021); called by mutect2, varscan2
- SPOCK2 | c.1151G>A p.G384E | Missense Mutation (SNP) | VAF 22/212 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- SSX1 | c.122A>G p.K41R | Missense Mutation (SNP) | VAF 40/208 reads (19%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.931); called by mutect2, varscan2
- TFB1M | c.496G>A p.V166I | Missense Mutation (SNP) | VAF 31/245 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.015); called by mutect2, varscan2
- TG | c.6887C>T p.A2296V | Missense Mutation (SNP) | VAF 26/224 reads (12%) | SIFT tolerated (0.67); PolyPhen benign (0.063); called by mutect2, varscan2
- VEPH1 | c.931T>A p.Y311N | Missense Mutation (SNP) | VAF 46/318 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); called by mutect2, varscan2
- WDR18 | c.880C>T p.R294C | Missense Mutation (SNP) | VAF 22/202 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.42); called by mutect2, varscan2
- ZNF106 | c.1849G>A p.G617S | Missense Mutation (SNP) | VAF 74/330 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0); called by mutect2, varscan2
- CCR8 | c.213T>C p.D71= | Silent (SNP) | VAF 34/338 reads (10%) | called by mutect2, varscan2
- CD226 | c.816C>T p.V272= | Silent (SNP) | VAF 15/137 reads (11%) | catalogued as rs750510644; called by mutect2, varscan2
- CD46 | c.*2_*4del | Silent (DEL) | VAF 22/238 reads (9%) | called by mutect2, pindel
- MGAT3 | c.462C>T p.S154= | Silent (SNP) | VAF 44/340 reads (13%) | catalogued as rs12628575; called by mutect2, varscan2
- OR10H3 | c.48C>A p.G16= | Silent (SNP) | VAF 24/226 reads (11%) | called by mutect2, varscan2
- SERTAD2 | c.417C>T p.D139= | Silent (SNP) | VAF 44/451 reads (10%) | catalogued as rs3770717; called by mutect2, varscan2
- SLAMF7 | c.174C>A p.T58= | Silent (SNP) | VAF 67/331 reads (20%) | catalogued as COSV100833285; called by mutect2, varscan2
- GPRC5B | c.*1960_*1961dup | 3'UTR (INS) | VAF 31/321 reads (10%) | called by mutect2, pindel, varscan2
- NSMCE2 | c.418+55G>T | Intron (SNP) | VAF 42/366 reads (11%) | called by mutect2, varscan2
